MMRF case MMRF_2061 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eb9eaeb1-53b6-4013-8406-59c9e2665c89

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 938 days (2.6 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.4 years (27,163 days); ISS stage: I; Days to last known disease status: 938 days (2.6 years); Days to last follow up: 938 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 44 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 47 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 85 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 86 days; Days to treatment end: 86 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 938.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 1.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.562 mg/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 22.7 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.13 µg/mL; Lactate Dehydrogenase 5.05 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.98 mmol/L; Albumin 36 g/L; Total Protein 9 g/dL; Glucose 5.34 mmol/L.
- Day 87 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.877 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.991 mg/dL; Immunoglobulin G 5.65 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 6.4 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.8 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 4.4 mmol/L.
- Day 186 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.463 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.803 mg/dL; Immunoglobulin G 8.87 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.17 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.8 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.79 mmol/L.
- Day 268 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.583 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.781 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.65 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 6.82 mmol/L.
- Day 359 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.953 mg/dL; Immunoglobulin G 6.6 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.63 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 4.79 mmol/L.
- Day 450 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.845 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 6.32 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.97 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.844 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.938 mg/dL; Immunoglobulin G 6.06 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.57 mmol/L.
- Day 645 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 7.96 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.53 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 8.75 mmol/L.
- Day 737 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.894 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 6.6 mmol/L.
- Day 828 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.682 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -5: Weight: 91 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2061_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2061_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
